Gene-level copy-number profile of tumor specimen TCGA-FX-A76Y-01A from TCGA case TCGA-FX-A76Y, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 49.8 years (18,181 days).
Specimen TCGA-FX-A76Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7b75decd-ac9b-4cab-bddc-293569eb4ad1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FX-A76Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c4e2cef-c077-4978-8e58-0a6c07f4628e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 7,731; copy number 2: 51,703; copy number 3: 304.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FX-A76Y-01A-11D-A350-01): tumor purity 0.91, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,488,963–48,578,088, 5 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr13:48,974,967–50,125,720, 36 genes (within-gene range 0–1): AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,082,484, 1 gene: AL137060.6.
- chr13:111,095,838–111,305,737, 8 genes (within-gene range 0–1): LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1.
- chr13:113,208,193–113,323,672, 4 genes (within-gene range 0–1): CUL4A, MIR8075, LDHBP1, LAMP1.
- chr17:7,549,099–7,711,372, 21 genes (within-gene range 0–1): TNFSF12-TNFSF13, AC016876.3, TNFSF13, SENP3, SENP3-EIF4A1, EIF4A1, AC016876.2, SNORA48, SNORD10, SNORA67, CD68, AC016876.1, MPDU1, SOX15, FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
